Gene-level copy-number profile of tumor specimen TCGA-08-0353-01A from TCGA case TCGA-08-0353, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.4 years (21,332 days).
Specimen TCGA-08-0353-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b5abd795-b716-4e84-8048-2a60fc9154ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-08-0353-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/771e35b1-030a-4649-9696-db129829749a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 64; copy number 1: 7,819; copy number 2: 47,965; copy number 3: 2,970; copy number 4: 486; copy number 7: 134; copy number 9: 361; copy number 26: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0353-01): tumor purity 0.85, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–1): MLLT3.
- chr9:20,502,265–22,214,672, 61 genes (broad region; genes not listed).
- chr9:22,703,516–23,438,700, 1 gene (within-gene range 0–1): AL391117.1.
- chr9:23,291,544–23,293,923, 1 gene: AL357614.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 510 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,234,861–198,222,513, 495 genes, copy number 7–9 (broad region; genes not listed).
- chr7:54,542,325–55,260,256, 15 genes, copy number 26 (within-gene range 3–26): VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.

Autosomal genes at a single copy (total copy number 1): 5,438. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
